HCMI case HCM-BROD-0100-C15 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e00914a1-997e-44ba-9c88-a5e8741b4ee1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1951; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.9; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Lower third of esophagus; Classification of tumor: primary; Age at diagnosis: 64.4 years (23,514 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic T: TX; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G3; Metastasis at diagnosis: Metastasis, NOS; Prior treatment: Yes; Sites of involvement: Esophagus, NOS.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 444 days (1.2 years); Days to treatment end: 483 days (1.3 years).
   Treatment given: Treatment type: Radiation, 3D Conformal; Treatment intent type: Neoadjuvant.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Neoadjuvant.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Esophagus, NOS; Days to progression: 0 days.
- Days to follow up: 781 days (2.1 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 748.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Reflux treatment type: Proton Pump Inhibitors; Risk factor treatment: Yes; Risk factors: GERD.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Alcohol intensity: Drinker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (3 samples)
- Sample HCM-BROD-0100-C15-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample HCM-BROD-0100-C15-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0100-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
